Somatic mutation profile of tumor specimen 0DUXPR from CCDI case PBCLWS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.7 years (3,187 days).
Specimen 0DUXPR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c658dc7-7bea-422b-9c09-2b9a8a08be81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUXNY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/096e1c90-fb6e-484a-9436-2b587ef2cb25

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 5, 5'UTR 2, Intron 1, Nonstop Mutation 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 210/290 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs137854557, CM1111787, CS992455, COSV62194445; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.3682C>T p.R1228C | Missense Mutation (SNP) | VAF 105/387 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201115102; called by muse, mutect2, varscan2
- BPIFC | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 105/408 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.982); catalogued as rs779345667, COSV55910731; called by muse, mutect2, varscan2
- DYSF | c.5688C>A p.D1896E | Missense Mutation (SNP) | VAF 62/339 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1558800113; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2804A>T p.Q935L | Missense Mutation (SNP) | VAF 31/324 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs1554416178; called by muse, mutect2, varscan2
- HSD3B2 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 174/436 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs748851282, COSV101027530; called by muse, mutect2, varscan2
- KLK3 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 97/191 reads (51%) | catalogued as rs769439514; called by muse, mutect2, varscan2
- MS4A1 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 112/304 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs147754874; called by muse, mutect2, varscan2
- NTRK2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 80/648 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); catalogued as COSV52870039; called by muse, mutect2, varscan2
- OBSCN | c.15826C>T p.R5276C | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs564170262, COSV52791013; called by muse, mutect2, varscan2
- PPFIA4 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 270/674 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as COSV55318273; called by muse, mutect2, varscan2
- RASSF10 | c.239C>A p.P80Q | Missense Mutation (SNP) | VAF 121/318 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.54); catalogued as rs377455730; called by muse, mutect2, varscan2
- SPEG | c.4100G>A p.S1367N | Missense Mutation (SNP) | VAF 112/432 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV100403408; called by muse, mutect2, varscan2
- URB1 | c.4990G>T p.D1664Y | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV66959803; called by muse, mutect2, varscan2
- ALG10 | c.1421A>C p.*474Sext*3 | Nonstop Mutation (SNP) | VAF 140/268 reads (52%) | called by muse, mutect2, varscan2
- BCORL1 | c.4047A>C p.Q1349H | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- BDH2 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLTCL1 | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 131/514 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP2 | c.1781T>C p.I594T | Missense Mutation (SNP) | VAF 283/651 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- COL4A2 | c.4945G>C p.D1649H | Missense Mutation (SNP) | VAF 11/384 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ERICH6B | c.1912del p.T638Pfs*21 | Frame Shift Del (DEL) | VAF 194/315 reads (62%) | called by mutect2, pindel, varscan2
- MRAP | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- STAB1 | c.2487G>T p.Q829H | Missense Mutation (SNP) | VAF 120/291 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- TEX15 | c.6663A>T p.K2221N (on ENST00000256246; = p.K2604N on NM_001350162.2) | Missense Mutation (SNP) | VAF 125/349 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ACOT11 | c.1572C>T p.R524= | Silent (SNP) | VAF 95/515 reads (18%) | catalogued as rs1557666439; called by muse, mutect2, varscan2
- C22orf42 | c.240C>T p.D80= | Silent (SNP) | VAF 35/222 reads (16%) | catalogued as rs761214648, COSV66076324; called by muse, mutect2, varscan2
- COL4A2 | c.4944G>A p.E1648= | Silent (SNP) | VAF 11/389 reads (3%) | called by muse, mutect2
- DMRT2 | c.1053C>T p.S351= | Silent (SNP) | VAF 74/350 reads (21%) | catalogued as rs113748895; called by muse, mutect2, varscan2
- FCRL5 | c.1740G>T p.G580= | Silent (SNP) | VAF 85/414 reads (21%) | catalogued as COSV100708830; called by muse, mutect2, varscan2
- ANKRD36B | c.-94G>T | 5'UTR (SNP) | VAF 53/90 reads (59%) | called by muse, mutect2, varscan2
- NHS | c.-49C>T | 5'UTR (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2
- PCOLCE | c.95+49C>T | Intron (SNP) | VAF 70/140 reads (50%) | called by muse, mutect2, varscan2
